Somatic mutation profile of tumor specimen MMRF_2778_1_BM_CD138pos (aliquot MMRF_2778_1_BM_CD138pos_T1_KHS5U_L15726) from MMRF case MMRF_2778, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.3 years (20,569 days).
Specimen MMRF_2778_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9740fd60-cf23-4351-a636-060df44d54b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2778_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2778_1_PB_WBC_C3_KHS5U_L15770; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea5d4f50-1062-4253-8fdc-6dc3eb005025

The open-access MAF lists 84 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 19, Silent 12, Intron 6, 5'Flank 4, RNA 3, Nonsense Mutation 3, 5'UTR 2, 3'Flank 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 104/246 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKR7L | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs112624478; called by muse, mutect2, varscan2
- CHIC1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as rs763197820; called by muse, mutect2, varscan2
- COL6A3 | c.3577C>T p.Q1193* | Nonsense Mutation (SNP) | VAF 6/138 reads (4%) | catalogued as rs865959630; called by muse, mutect2
- CREBBP | c.4993G>A p.D1665N | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52116133; called by muse, mutect2
- CXCR4 | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV99603303; called by muse, mutect2, varscan2
- GNPDA1 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs762824840; called by muse, mutect2, varscan2
- IGLV3-1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs368499668; called by muse, varscan2
- IGLV4-3 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs759083415; called by muse, mutect2, varscan2
- IKBKB | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 5/114 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100645808, COSV60598802, COSV60598896; called by muse, mutect2
- NCAPD3 | c.3942G>T p.Q1314H | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV73188019; called by muse, varscan2
- NHS | c.2846C>T p.T949M | Missense Mutation (SNP) | VAF 117/250 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373464879; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA4 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as rs1554124966, COSV63538887; called by muse, mutect2, varscan2
- PROM1 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as rs770268627, COSV71699154; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RFT1 | c.1275G>A p.W425* | Nonsense Mutation (SNP) | VAF 36/157 reads (23%) | catalogued as rs777100628, COSV56248175; called by muse, mutect2, varscan2
- SPIN1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV65498591; called by muse, mutect2, varscan2
- TMEM232 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT tolerated (1); PolyPhen possibly damaging (0.742); catalogued as COSV70267992; called by muse, mutect2, varscan2
- AKR7A2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANKRD2 | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- BCHE | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- C8orf33 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CCNB3 | c.4058G>T p.S1353I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- DACH2 | c.1445A>G p.Q482R | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FGFR1 | c.2089G>A p.G697S (on ENST00000447712 / NM_023110.3; = p.G695S on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/242 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT1 | c.512dup p.F172Vfs*4 | Frame Shift Ins (INS) | VAF 19/149 reads (13%) | called by mutect2, pindel, varscan2
- KLHL31 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- LRP5 | c.4303C>T p.L1435F | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- NCAPD3 | c.3941A>G p.Q1314R | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, varscan2
- PCDHGB2 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 87/217 reads (40%) | called by muse, mutect2, varscan2
- SDK2 | c.5342A>G p.N1781S | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCTN2 | c.1252T>C p.F418L | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- TFR2 | c.1819C>G p.L607V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TH | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 33/146 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TNPO1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- WASHC4 | c.28T>A p.W10R | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, varscan2
- ZNF606 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- CDH22 | c.1239C>T p.V413= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100953004, COSV64836522; called by muse, mutect2
- GRIN2D | c.660G>A p.A220= | Silent (SNP) | VAF 85/182 reads (47%) | catalogued as rs1473256750; called by muse, mutect2, varscan2
- HMCN2 | c.11220C>T p.S3740= | Silent (SNP) | VAF 65/176 reads (37%) | called by muse, mutect2, varscan2
- IPO11 | c.294C>T p.F98= | Silent (SNP) | VAF 9/213 reads (4%) | called by muse, mutect2
- ISLR2 | c.1386G>T p.G462= | Silent (SNP) | VAF 14/350 reads (4%) | called by muse, mutect2
- KRT74 | c.789C>A p.A263= | Silent (SNP) | VAF 56/100 reads (56%) | called by muse, mutect2, varscan2
- LAMB3 | c.2835G>A p.V945= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- MAMDC2 | c.1467T>C p.I489= | Silent (SNP) | VAF 82/269 reads (30%) | catalogued as COSV65852562; called by muse, mutect2, varscan2
- NBEA | c.2811C>A p.V937= | Silent (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- RFX5 | c.312T>C p.T104= | Silent (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- SLC12A4 | c.1689C>G p.L563= | Silent (SNP) | VAF 96/104 reads (92%) | called by muse, mutect2, varscan2
- UNC80 | c.5421C>T p.R1807= | Silent (SNP) | VAF 66/131 reads (50%) | called by muse, mutect2, varscan2
- AC016582.2 | chr19:37794017 T>C | 3'Flank (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- ACACA | c.339-14726T>G | Intron (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- ARMC10 | c.245-1782C>G | Intron (SNP) | VAF 12/275 reads (4%) | called by muse, mutect2
- BARD1 | c.*409T>A | 3'UTR (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021496 G>A | 5'Flank (SNP) | VAF 78/180 reads (43%) | catalogued as rs531225220; called by muse, mutect2, varscan2
- BRINP2 | c.*562T>C | 3'UTR (SNP) | VAF 9/285 reads (3%) | called by muse, mutect2
- CASP2 | c.*700G>A | 3'UTR (SNP) | VAF 59/125 reads (47%) | catalogued as rs1304358196; called by muse, mutect2, varscan2
- CBY1 | c.*128G>T | 3'UTR (SNP) | VAF 68/157 reads (43%) | called by muse, mutect2, varscan2
- CCDC61 | c.149-45T>A | Intron (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- CD99 | c.67+644G>A | Intron (SNP) | VAF 20/158 reads (13%) | called by muse, mutect2, varscan2
- CEP41 | chr7:130441124 C>T | 5'Flank (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2
- CXXC1 | c.-57G>A | 5'UTR (SNP) | VAF 54/279 reads (19%) | called by muse, mutect2, varscan2
- DHX9 | c.*408A>G | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- EPHA5 | c.*1508T>G | 3'UTR (SNP) | VAF 53/93 reads (57%) | called by muse, mutect2, varscan2
- EPPK1 | c.*195G>T | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- ERP44 | c.*832T>A | 3'UTR (SNP) | VAF 28/80 reads (35%) | called by muse, varscan2
- FRMPD3 | c.*829A>G | 3'UTR (SNP) | VAF 63/165 reads (38%) | catalogued as rs1391158949; called by muse, mutect2, varscan2
- FTO | c.*9112G>C | 3'UTR (SNP) | VAF 41/42 reads (98%) | called by muse, mutect2, varscan2
- HDX | c.*823C>T | 3'UTR (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- LAMA5 | chr20:62308889 T>C | 3'Flank (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- LINC02228 | n.347G>A | RNA (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- LRP4 | c.*380C>T | 3'UTR (SNP) | VAF 104/373 reads (28%) | called by muse, mutect2, varscan2
- MFRP | chr11:119343934 C>T | 5'Flank (SNP) | VAF 77/354 reads (22%) | catalogued as rs553614519, COSV100793301; ClinVar: uncertain significance; called by muse, varscan2
- MIR200A | n.88C>T | RNA (SNP) | VAF 14/56 reads (25%) | catalogued as rs774635553; called by muse, mutect2, varscan2
- MIR498 | n.56C>T | RNA (SNP) | VAF 33/92 reads (36%) | called by muse, mutect2, varscan2
- NCMAP | c.*262G>A | 3'UTR (SNP) | VAF 62/149 reads (42%) | called by muse, varscan2
- RAP2C | c.-385_-376del | 5'UTR (DEL) | VAF 14/24 reads (58%) | called by mutect2, varscan2
- SHROOM4 | c.*998-1168T>C | Intron (SNP) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- SLC19A2 | chr1:169486403 T>A | 5'Flank (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- SLC25A53 | c.*1943C>G | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- SLCO2B1 | c.*589_*590insT | 3'UTR (INS) | VAF 64/285 reads (22%) | called by mutect2, pindel*, varscan2
- TIMP3 | c.*305dup | 3'UTR (INS) | VAF 39/83 reads (47%) | called by mutect2, varscan2
- TMEM147 | c.148-31G>C | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- USP13 | c.*5220T>G | 3'UTR (SNP) | VAF 59/112 reads (53%) | called by muse, mutect2, varscan2
- ZNF212 | c.*807G>A | 3'UTR (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- ZNF25 | c.*1875C>T | 3'UTR (SNP) | VAF 4/41 reads (10%) | catalogued as rs1421283877, COSV100224612; called by muse, mutect2, varscan2
